Somatic mutation profile of tumor specimen C3L-03679-01 (aliquot CPT0189950006) from CPTAC case C3L-03679, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 71.3 years (26,038 days).
Specimen C3L-03679-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa522e6e-287a-4ab7-8010-9b5616956927.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03679-31 (Blood Derived Normal), aliquot CPT0191100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1fe2d61-7694-452b-a44c-e168f6f9a27d

The open-access MAF lists 98 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Nonsense Mutation 5, Intron 5, 5'UTR 4, Splice Site 4, 3'UTR 3, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 75/275 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF2 | c.2936G>T p.G979V (on ENST00000361247 / NM_001162383.2; = p.G951V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as COSV58114395; called by muse, mutect2, varscan2
- ATP8B4 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 45/377 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs745355532, COSV52708582; called by muse, mutect2, varscan2
- BCAS3 | c.1807+1G>A p.X603_splice (on ENST00000390652 / NM_001353144.2; = p.X588_splice on NM_017679.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 21/134 reads (16%) | catalogued as rs1393390703; called by muse, mutect2, varscan2
- CCDC168 | c.10681G>C p.E3561Q | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV59425523; called by muse, mutect2, varscan2
- CHD7 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs942764555; called by muse, mutect2, varscan2
- CROCC | c.5326G>A p.A1776T | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as rs760822070; called by muse, mutect2, varscan2
- CYYR1 | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1371255873, COSV54836151, COSV99051262; called by muse, mutect2, varscan2
- ERVW-1 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 33/258 reads (13%) | catalogued as rs1038278481, COSV71259665; called by muse, mutect2, varscan2
- GABRG2 | c.1268G>T p.R423L (on ENST00000361925 / NM_001375343.1; = p.R383L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs528036202, COSV62716272, COSV62721034; called by muse, mutect2, varscan2
- GUCY2C | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs943418717, COSV53787842; called by muse, mutect2, varscan2
- IGFBP1 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV51874630; called by muse, mutect2, varscan2
- IQGAP2 | c.2905G>A p.V969I | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as rs775261663; called by muse, mutect2
- ITPR2 | c.2560G>T p.D854Y | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs1199548032; called by muse, mutect2
- KIAA0930 | c.657+1G>C p.X219_splice (on ENST00000336156 / NM_001009880.2; = p.X224_splice on NM_015264.2) | Splice Site (SNP) | VAF 11/124 reads (9%) | catalogued as rs1243316582; called by muse, mutect2
- MAGEB6B | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as rs751404306, COSV69689551; called by muse, mutect2, varscan2
- MFSD6L | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490853824; called by muse, mutect2, varscan2
- MYOM2 | c.1307C>A p.P436Q | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs150903286, COSV100037464; called by muse, mutect2, varscan2
- NCOR2 | c.5435A>G p.K1812R | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.991); catalogued as rs375889764; called by muse, mutect2
- NCOR2 | c.5433A>C p.E1811D | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs369739293; called by muse, mutect2
- NWD1 | c.4013G>T p.G1338V | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1394325921; called by muse, mutect2, varscan2
- OR10J3 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 47/447 reads (11%) | catalogued as rs1024804567; called by muse, mutect2, varscan2
- P2RX5 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs780739223; called by muse, varscan2
- PARP8 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); catalogued as rs186735992, COSV55856242; called by muse, mutect2, varscan2
- PRH1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs372677799; called by muse, varscan2
- RBM20 | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1024449251; called by muse, mutect2, varscan2
- ROBO1 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747155572; called by muse, mutect2, varscan2
- SRRM4 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 50/402 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs1181422252, COSV57428449; called by muse, mutect2, varscan2
- ZNF174 | c.113dup p.N38Kfs*6 | Frame Shift Ins (INS) | VAF 43/336 reads (13%) | catalogued as rs778043537; called by mutect2, varscan2
- ZNF267 | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV56253429; called by muse, mutect2, varscan2
- ADAMTS2 | c.460_462del p.S154del | In Frame Del (DEL) | VAF 26/180 reads (14%) | called by mutect2, pindel*
- AEBP2 | c.297G>C p.E99D | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- APBA2 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CACNA1E | c.2632C>A p.Q878K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPA | c.3938G>A p.G1313E (on ENST00000334218 / NM_001366019.2; = p.G1300E on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CELF6 | c.583C>A p.H195N | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DGKB | c.881G>A p.C294Y | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH12 | c.8910G>T p.L2970F (on ENST00000351747; = p.L3838F on NM_001366028.2) | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- DNAH8 | c.4666C>T p.P1556S | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.3977T>A p.V1326D | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FHOD3 | c.3278T>C p.I1093T (on ENST00000359247 / NM_001281739.3; = p.I1110T on NM_025135.5) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- FLT1 | c.2531C>A p.A844E | Missense Mutation (SNP) | VAF 70/508 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT1 | c.2356-1G>T p.X786_splice | Splice Site (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- FSIP2 | c.14988C>A p.F4996L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- GDAP2 | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- HCRT | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, varscan2
- IGHV3OR16-9 | c.186C>A p.D62E | Missense Mutation (SNP) | VAF 124/508 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IRX2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, varscan2
- ITPR2 | c.2558G>T p.G853V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.206); called by muse, mutect2
- KCNQ2 | c.1411C>T p.Q471* (on ENST00000359125 / NM_172107.4; = p.Q443* on NM_004518.6) | Nonsense Mutation (SNP) | VAF 73/433 reads (17%) | called by muse, mutect2, varscan2
- KIAA1217 | c.2996T>C p.M999T | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KRTAP10-1 | c.242A>T p.Q81L | Missense Mutation (SNP) | VAF 123/719 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- NCAPH | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NKX2-1 | c.839_885del p.A280Gfs*113 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel
- NOX5 | c.1692G>T p.K564N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PSMC5 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- RYR2 | c.5341G>C p.E1781Q | Missense Mutation (SNP) | VAF 124/374 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SACS | c.6933C>G p.Y2311* | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | called by muse, mutect2, varscan2
- SCARB1 | c.630+1G>T p.X210_splice | Splice Site (SNP) | VAF 20/380 reads (5%) | called by muse, mutect2
- SHANK1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SRRM3 | c.1679T>G p.I560S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TLR8 | c.1075A>G p.I359V (on ENST00000218032 / NM_138636.5; = p.I377V on NM_016610.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TNC | c.3766G>T p.V1256F | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TOMM20L | c.240G>T p.M80I | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TRIM26 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- TRPM8 | c.1154T>A p.L385H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TSEN54 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 48/610 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2
- ZC3H7B | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATP6V1B1 | c.189G>A p.A63= | Silent (SNP) | VAF 56/413 reads (14%) | catalogued as rs376581983, COSV99314366; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BEND4 | c.417C>T p.G139= | Silent (SNP) | VAF 37/226 reads (16%) | catalogued as rs772220241; called by muse, mutect2, varscan2
- CBX8 | c.990G>A p.R330= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs907615634; called by muse, mutect2, varscan2
- CCDC168 | c.16410A>G p.T5470= | Silent (SNP) | VAF 35/159 reads (22%) | called by muse, mutect2, varscan2
- FHDC1 | c.615A>G p.G205= | Silent (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- FPR2 | c.972C>A p.A324= | Silent (SNP) | VAF 40/392 reads (10%) | catalogued as COSV60672675; called by muse, mutect2, varscan2
- GOLGA8S | c.564C>T p.T188= | Silent (SNP) | VAF 41/900 reads (5%) | catalogued as rs761701790; called by muse, mutect2
- GRIN2D | c.1128C>T p.F376= | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- HTRA1 | c.579G>A p.P193= | Silent (SNP) | VAF 49/477 reads (10%) | catalogued as rs772327746, COSV64565459; called by muse, mutect2, varscan2
- KCNG1 | c.129G>A p.A43= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1245527335, COSV65368166; called by muse, mutect2, varscan2
- NWD1 | c.4014G>T p.G1338= | Silent (SNP) | VAF 27/261 reads (10%) | called by muse, mutect2, varscan2
- PGM5 | c.1254C>T p.V418= | Silent (SNP) | VAF 21/187 reads (11%) | catalogued as rs782284984; called by muse, mutect2, varscan2
- PIGS | c.12C>T p.A4= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs760363499; called by muse, mutect2, varscan2
- PYCR1 | c.471C>A p.G157= | Silent (SNP) | VAF 63/497 reads (13%) | called by muse, mutect2, varscan2
- STARD9 | c.8511C>T p.C2837= | Silent (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- SV2A | c.537C>T p.D179= | Silent (SNP) | VAF 33/329 reads (10%) | catalogued as rs781860737, COSV64966188; called by muse, mutect2, varscan2
- TNRC6A | c.2421T>C p.D807= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- WRN | c.3753A>G p.K1251= | Silent (SNP) | VAF 49/236 reads (21%) | called by muse, mutect2, varscan2
- AGGF1 | c.-356T>A | 5'UTR (SNP) | VAF 14/92 reads (15%) | called by muse, varscan2
- AKR1B1 | c.-33G>T | 5'UTR (SNP) | VAF 35/235 reads (15%) | called by muse, mutect2, varscan2
- CEP41 | c.*2468G>T | 3'UTR (SNP) | VAF 31/270 reads (11%) | called by muse, mutect2, varscan2
- CYP4F12 | c.-2+32T>A | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- LINC01551 | n.1255-5426G>T | Intron (SNP) | VAF 12/35 reads (34%) | called by muse, varscan2
- NRM | c.133+145A>G | Intron (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- NUP214 | c.-73C>G | 5'UTR (SNP) | VAF 8/65 reads (12%) | catalogued as rs1182788577, COSV99908253; called by muse, mutect2, varscan2
- PUSL1 | c.*107C>T | 3'UTR (SNP) | VAF 50/281 reads (18%) | called by muse, mutect2, varscan2
- RGS9BP | c.*42G>A | 3'UTR (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2
- THOC6 | c.362+20T>C | Intron (SNP) | VAF 70/278 reads (25%) | called by muse, mutect2, varscan2
- TNFRSF13B | c.-33C>G | 5'UTR (SNP) | VAF 20/383 reads (5%) | called by muse, mutect2
- TUBA4A | c.4-585G>A | Intron (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
